Somatic mutation profile of tumor specimen 0DVXFK from CCDI case PBCNEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,467 days).
Specimen 0DVXFK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e879575-1c11-4e4b-9938-b054b48ce60c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adbd97f9-6502-4cfe-9133-585f1dc9777e

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANXA4 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 317/650 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs113756102; called by muse, mutect2, varscan2
- FAM120AOS | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 632/1324 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV52908480; called by muse, mutect2
- FGD2 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 216/415 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1433961646; called by muse, mutect2, varscan2
- GRIP1 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 115/487 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs770020880; called by muse, mutect2, varscan2
- HMCN1 | c.5066G>A p.R1689H | Missense Mutation (SNP) | VAF 23/487 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs761113225, COSV54903438; called by muse, mutect2
- PPP1R16B | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 173/468 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs1234041875, COSV55375293; called by muse, mutect2, varscan2
- DEFB121 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 149/366 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by mutect2, varscan2
- FMO4 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by muse, mutect2
- PLEKHG4 | c.95G>A p.W32* | Nonsense Mutation (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- RNF122 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- C11orf16 | c.870G>A p.T290= | Silent (SNP) | VAF 62/500 reads (12%) | catalogued as rs765273949; called by muse, mutect2, varscan2
- TMCO3 | c.1545G>A p.T515= | Silent (SNP) | VAF 64/450 reads (14%) | catalogued as rs148613524; called by muse, mutect2, varscan2
- AMBRA1 | c.2421-46C>T | Intron (SNP) | VAF 82/182 reads (45%) | catalogued as rs956191105, COSV54062473; called by muse, mutect2, varscan2
- CC2D1A | c.1223-84G>T | Intron (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
